MMRF case MMRF_1484 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/41c1b266-699e-463d-9107-d13790630da1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.4 years (26,439 days); ISS stage: II; Days to last known disease status: 1,050 days (2.9 years); Days to last follow up: 1,050 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -29 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 78.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Beta 2 Microglobulin 5 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 292 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 74 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 24.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Beta 2 Microglobulin 6.89 µg/mL; Hemoglobin 5.7 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 256 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 5.1 g/dL; Glucose 8.69 mmol/L.
- Day 144 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 7.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Beta 2 Microglobulin 4.96 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 256 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 6.55 mmol/L.
- Day 256 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 5.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 6.86 g/L; Beta 2 Microglobulin 7.62 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 565 ×10⁹/L; Creatinine 256 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 9.52 mmol/L.
- Day 339 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 4.18 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 7.38 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 283 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 8.25 mmol/L.
- Day 423 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 5.26 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 248 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.
- Day 521 (ECOG 0): Beta 2 Microglobulin 4.96 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 14.4 ×10⁹/L; Absolute Neutrophil 10.6 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 265 µmol/L; Blood Urea Nitrogen 22.1 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 6.16 mmol/L.
- Day 591 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Beta 2 Microglobulin 6.64 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 13.6 ×10⁹/L; Absolute Neutrophil 12.9 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 248 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 8.8 mmol/L.
- Day 696 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 4.96 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 5.98 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 256 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 6.05 mmol/L.
- Day 844 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Beta 2 Microglobulin 5.56 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 265 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 7.1 mmol/L.
- Day 914 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 269 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 1,050 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 7.22 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 5.92 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 274 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -29: Weight: 107 kg; Height: 185 cm.

Biospecimens (3 samples)
- Sample MMRF_1484_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -29 days.
- Sample MMRF_1484_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -29 days.
- Sample MMRF_1484_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 423 days (1.2 years).
